Somatic mutation profile of tumor specimen TARGET-20-PASPTM-09A (aliquot TARGET-20-PASPTM-09A-01D) from TARGET case TARGET-20-PASPTM, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.0 years (5,122 days).
Specimen TARGET-20-PASPTM-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3407858c-4f21-4daa-8aa6-9f5aacca2a20.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASPTM-14A (Bone Marrow Normal), aliquot TARGET-20-PASPTM-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0a82e692-1668-4ef1-8131-cf947e9f2300

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2447A>T p.D816V | Missense Mutation (SNP) | VAF 51/338 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs121913507, CM952169, COSV55386424, COSV55388612, COSV55408930; ClinVar: other / uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 29/409 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- GATA2 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62003120, COSV62003236, COSV62003503; called by muse, mutect2, varscan2
- GATA2 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV62003359; called by muse, mutect2, varscan2
- RAD21 | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 176/376 reads (47%) | catalogued as COSV52059672, COSV52063974; called by muse, mutect2, varscan2
- ASXL2 | c.1331_1335del p.K444Rfs*3 | Frame Shift Del (DEL) | VAF 164/401 reads (41%) | called by mutect2, pindel, varscan2
